Somatic mutation profile of tumor specimen MMRF_2696_1_BM_CD138pos (aliquot MMRF_2696_1_BM_CD138pos_T1_KHS5U_L14422) from MMRF case MMRF_2696, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 49.5 years (18,092 days).
Specimen MMRF_2696_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af7dd49a-cf44-4f7e-859a-61f0221635e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2696_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2696_1_PB_WBC_C2_KHS5U_L14423; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15e9949f-3d55-4509-a852-841d719c215e

The open-access MAF lists 105 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 25, Silent 14, Intron 11, 5'UTR 4, 5'Flank 3, 3'Flank 3, Nonsense Mutation 2, Frame Shift Ins 2, RNA 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 29/69 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APCS | c.153C>A p.N51K | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV54818831; called by muse, mutect2, varscan2
- CLCN1 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as CM139480, COSV58369313; called by muse, mutect2, varscan2
- DOCK6 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs1193584150, COSV52948979; called by muse, mutect2, varscan2
- DUOX2 | c.3163G>A p.V1055M | Missense Mutation (SNP) | VAF 74/358 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs367803824, COSV66530997; called by muse, mutect2, varscan2
- GPC6 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 47/49 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1391009706, COSV104425017; called by muse, mutect2, varscan2
- H1-4 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs202237797; called by muse, mutect2, varscan2
- H2BC21 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 110/226 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.414); catalogued as COSV100479686; called by muse, mutect2, varscan2
- IGHV2-70 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs370737142; called by muse, varscan2
- IGHV2-70 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs369724963; called by muse, varscan2
- IGKV4-1 | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 57/62 reads (92%) | catalogued as rs778196241; called by muse, mutect2, varscan2
- KRT79 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs199955846, COSV57940423; called by muse, mutect2, varscan2
- OAF | c.424A>G p.M142V | Missense Mutation (SNP) | VAF 86/363 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs1432103988; called by muse, mutect2, varscan2
- OR52E2 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV58612181; called by muse, mutect2, varscan2
- PDE8A | c.2284G>A p.V762M | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781503959, COSV59636710; called by muse, mutect2, varscan2
- PDZD11 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1390645328, COSV52105343; called by muse, mutect2, varscan2
- PTPRS | c.3335C>T p.T1112M | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.454); catalogued as rs201447856; called by muse, mutect2, varscan2
- SMAD7 | c.626dup p.P210Sfs*25 | Frame Shift Ins (INS) | VAF 40/106 reads (38%) | catalogued as rs747624971; called by mutect2, varscan2
- TSHZ3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs750208331, COSV53663688; called by muse, mutect2, varscan2
- ABLIM2 | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C6orf132 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CAMK2D | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 134/297 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- CENPS-CORT | c.37T>A p.F13I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CHST14 | c.1026T>G p.S342R | Missense Mutation (SNP) | VAF 89/441 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DCAF11 | c.-214+5G>A | Splice Region (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2
- GNB2 | c.46A>C p.N16H | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- H2BC9 | c.15dup p.K6* | Frame Shift Ins (INS) | VAF 65/181 reads (36%) | called by mutect2, pindel, varscan2
- HAP1 | c.1472T>C p.L491P (on ENST00000310778 / NM_001367460.1; = p.L439P on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- IQGAP2 | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- MAGEE2 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MPZL1 | c.121T>A p.Y41N | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, varscan2
- NOP9 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPSS2 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 87/445 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAX6 | c.469_471del p.G157del | In Frame Del (DEL) | VAF 75/285 reads (26%) | called by mutect2, pindel, varscan2
- PTPMT1 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); called by muse, mutect2
- RBBP5 | c.1317G>C p.Q439H | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- RICTOR | c.4958A>C p.Y1653S | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF44 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- RPS28 | c.199A>G p.R67G | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- SLC4A2 | c.2421G>A p.M807I | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLITRK2 | c.25A>G p.S9G | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- TUBGCP6 | c.1479_1480insCGGGTG p.A493_A494insRV | In Frame Ins (INS) | VAF 23/63 reads (37%) | called by mutect2, pindel*, varscan2*
- UBAP1 | c.159+2T>A p.X53_splice | Splice Site (SNP) | VAF 28/173 reads (16%) | called by muse, mutect2, varscan2
- UHRF2 | c.123A>C p.E41D | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.029); called by muse, varscan2
- ACAN | c.1032C>T p.Y344= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as rs762147927, COSV61357432; called by muse, mutect2, varscan2
- BEND5 | c.975G>A p.T325= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as rs753334745, COSV65716710; called by muse, mutect2, varscan2
- COLGALT1 | c.1122C>T p.A374= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs779994127; called by muse, varscan2
- DEFB1 | c.153C>A p.I51= | Silent (SNP) | VAF 93/206 reads (45%) | catalogued as rs553835551; called by muse, mutect2, varscan2
- DIO3 | c.213C>T p.F71= | Silent (SNP) | VAF 117/254 reads (46%) | called by muse, mutect2, varscan2
- DSE | c.936G>A p.A312= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs543521325; called by muse, varscan2
- IGLL5 | c.78G>A p.L26= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs551962377, COSV73250938; called by muse, mutect2, varscan2
- IL36G | c.45C>T p.V15= | Silent (SNP) | VAF 74/144 reads (51%) | called by muse, mutect2, varscan2
- KCNIP4 | c.213A>G p.E71= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2
- KIF17 | c.1998T>C p.A666= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- MUC2 | c.894C>T p.F298= | Silent (SNP) | VAF 136/422 reads (32%) | catalogued as rs772293718; called by muse, mutect2, varscan2
- RNF186 | c.300C>T p.R100= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs201262383; called by muse, mutect2, varscan2
- TACC2 | c.5961G>A p.P1987= (on ENST00000334433; = p.P65= on NM_006997.4) | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as rs144751396; called by muse, mutect2, varscan2
- TMEM47 | c.189C>T p.S63= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- ANKRD55 | c.*71G>C | 3'UTR (SNP) | VAF 59/330 reads (18%) | called by muse, mutect2, varscan2
- ANO6 | c.-132G>A | 5'UTR (SNP) | VAF 13/42 reads (31%) | catalogued as rs1485830349; called by muse, mutect2, varscan2
- ARHGEF7 | c.*377C>G | 3'UTR (SNP) | VAF 26/33 reads (79%) | called by muse, mutect2, varscan2
- ATR | c.7761+1370del | Intron (DEL) | VAF 5/27 reads (19%) | catalogued as rs766238891, COSV53813401; called by pindel, varscan2
- B4GALT6 | c.*1005del | 3'UTR (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- CAMK2D | chr4:113761382 T>C | 5'Flank (SNP) | VAF 43/77 reads (56%) | called by muse, mutect2, varscan2
- CCSAP | c.*1660T>G | 3'UTR (SNP) | VAF 42/100 reads (42%) | called by muse, mutect2, varscan2
- CISD2 | c.*1858T>A | 3'UTR (SNP) | VAF 37/125 reads (30%) | called by muse, mutect2, varscan2
- CLK2P1 | n.637C>T | RNA (SNP) | VAF 85/267 reads (32%) | called by muse, mutect2, varscan2
- CRYBG2 | c.4454+63G>A | Intron (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- EFNB1 | c.*779T>G | 3'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- ELP4 | chr11:31787403 G>A | 3'Flank (SNP) | VAF 14/291 reads (5%) | called by muse, mutect2
- FAM131B | c.*1985C>T | 3'UTR (SNP) | VAF 76/278 reads (27%) | called by muse, mutect2, varscan2
- FAM189A1 | c.*1613T>C | 3'UTR (SNP) | VAF 85/333 reads (26%) | called by muse, mutect2, varscan2
- FH | c.*101C>T | 3'UTR (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- FOXK2 | c.*1179A>G | 3'UTR (SNP) | VAF 66/146 reads (45%) | catalogued as rs1381268128; called by muse, mutect2, varscan2
- GNA14 | c.*179A>C | 3'UTR (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- GRIK2 | c.2563-4350A>G | Intron (SNP) | VAF 104/274 reads (38%) | called by muse, mutect2, varscan2
- GTPBP10 | c.*1745G>T | 3'UTR (SNP) | VAF 15/52 reads (29%) | catalogued as rs1313663026; called by muse, mutect2, varscan2
- IL6ST | c.*4060T>A | 3'UTR (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- INKA2 | c.*1270T>C | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- ITIH5 | c.*3073G>A | 3'UTR (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2, varscan2
- KAT6B | c.-168T>A | 5'UTR (SNP) | VAF 44/196 reads (22%) | called by muse, mutect2, varscan2
- KCNMB2 | c.*1215A>C | 3'UTR (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- LCP2 | chr5:170297789 G>T | 5'Flank (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- LTB | c.163-144_163-97del | Intron (DEL) | VAF 92/287 reads (32%) | called by mutect2, pindel
- MIR5195 | chr14:106851256 T>G | 5'Flank (SNP) | VAF 105/241 reads (44%) | catalogued as rs749956333; called by muse, mutect2, varscan2
- MPZL1 | c.92-43T>C | Intron (SNP) | VAF 20/62 reads (32%) | called by muse, varscan2
- NPAS3 | chr14:33801430 C>T | 3'Flank (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- OPCML | c.-234T>G | 5'UTR (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- PLEKHG3 | chr14:64749030 G>A | 3'Flank (SNP) | VAF 23/75 reads (31%) | catalogued as rs1447033362; called by muse, mutect2, varscan2
- PRKACB | c.-206C>T | 5'UTR (SNP) | VAF 5/38 reads (13%) | catalogued as rs1557887994, COSV65771414; called by mutect2, varscan2
- PTGER2 | c.*584A>G | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- RASSF2 | c.*4211T>G | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- RSBN1 | c.*2026A>T | 3'UTR (SNP) | VAF 6/34 reads (18%) | catalogued as rs943627236, COSV99792880; called by mutect2, varscan2
- RTKN | c.*388T>G | 3'UTR (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- SFMBT2 | c.525+98C>A | Intron (SNP) | VAF 73/319 reads (23%) | catalogued as COSV62810396; called by muse, mutect2, varscan2
- SLC1A2 | c.*3417T>G | 3'UTR (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- SLC9A7 | c.*764C>T | 3'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- SMU1 | c.*72_*73insCT | 3'UTR (INS) | VAF 32/87 reads (37%) | called by pindel, varscan2
- SMU1 | c.*10T>G | 3'UTR (SNP) | VAF 22/58 reads (38%) | called by muse, varscan2
- SPICE1 | c.-1+349C>G | Intron (SNP) | VAF 43/137 reads (31%) | called by muse, mutect2, varscan2
- SRP14 | c.98-120_98-119insTGTT | Intron (INS) | VAF 21/142 reads (15%) | called by mutect2, pindel, varscan2
- TSPAN32 | c.181+453G>T | Intron (SNP) | VAF 33/131 reads (25%) | called by muse, mutect2, varscan2
- TSPAN5 | c.279+2157A>T | Intron (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- TTC23L | c.841-73C>T | Intron (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2
- ZNF596 | c.*413A>G | 3'UTR (SNP) | VAF 39/66 reads (59%) | called by muse, mutect2, varscan2
